Somatic mutation profile of tumor specimen MP2PRT-PANUYZ-TMP1-A (aliquot MP2PRT-PANUYZ-TMP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PANUYZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.9 years (676 days).
Specimen MP2PRT-PANUYZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2a0f4cb-c7f5-47ff-b359-02e10be620f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANUYZ-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANUYZ-NM1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3b9f2f2-3c28-4fcc-abef-56a1ef0278bc

The open-access MAF lists 15 somatic variants for this specimen: 9 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 8, Silent 6, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACCS | c.998G>A p.G333D | Missense Mutation (SNP) | VAF 134/411 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV55459505; called by muse, mutect2, varscan2
- PLCD3 | c.1135C>T p.R379C | Missense Mutation (SNP) | VAF 45/438 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779191448; called by muse, mutect2, varscan2
- SRD5A3 | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 26/455 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs759599389; called by muse, mutect2
- UGT2B7 | c.239C>A p.S80Y | Missense Mutation (SNP) | VAF 83/306 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.891); catalogued as rs373528265; called by muse, mutect2, varscan2
- CENPB | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 53/915 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.159); called by muse, mutect2
- CPZ | c.1189dup p.Q397Pfs*24 (on ENST00000360986 / NM_001014447.3; = p.Q386Pfs*24 on NM_003652.3) | Frame Shift Ins (INS) | VAF 113/471 reads (24%) | called by mutect2, pindel, varscan2
- SEC14L5 | c.503A>C p.N168T | Missense Mutation (SNP) | VAF 110/379 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- SRPRA | c.1523T>C p.F508S | Missense Mutation (SNP) | VAF 38/240 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.062); called by mutect2, varscan2
- ZNF609 | c.1348C>A p.L450M | Missense Mutation (SNP) | VAF 49/465 reads (11%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.757); called by muse, mutect2
- ANKK1 | c.138G>A p.T46= | Silent (SNP) | VAF 56/760 reads (7%) | catalogued as rs537006404; called by muse, mutect2
- CIC | c.903G>A p.S301= | Silent (SNP) | VAF 163/488 reads (33%) | catalogued as rs769787910; called by muse, mutect2, varscan2
- INTS13 | c.1353G>A p.Q451= | Silent (SNP) | VAF 129/360 reads (36%) | called by muse, mutect2, varscan2
- PADI1 | c.1737G>A p.A579= | Silent (SNP) | VAF 79/255 reads (31%) | catalogued as rs762129125; called by muse, mutect2, varscan2
- SLC8A2 | c.1320G>A p.A440= | Silent (SNP) | VAF 54/529 reads (10%) | catalogued as rs1334571599, COSV99370296; called by muse, mutect2, varscan2
- VRTN | c.1947G>A p.T649= | Silent (SNP) | VAF 63/582 reads (11%) | catalogued as rs777175973, COSV56439410; called by muse, mutect2, varscan2
